Gene-level copy-number profile of tumor specimen TCGA-KN-8419-01A from TCGA case TCGA-KN-8419, project TCGA-KICH (Kidney Chromophobe). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, chromophobe type; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Age at diagnosis: 43.2 years (15,769 days).
Specimen TCGA-KN-8419-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-KICH.d2138551-faf1-4d77-a099-119571ec7569.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-KN-8419-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 350 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/455090e6-14fe-4216-b819-b1d10b0f307b

Most common (modal) total copy number across autosomal genes: 0 — below the diploid value of 2.
Genes by total copy number (all chromosomes): copy number 0: 34,060; copy number 1: 674; copy number 2: 649; copy number 3: 17,866; copy number 4: 81; copy number 5: 3,234; copy number 6: 3,701; copy number 7: 1; copy number 8: 1; copy number 9: 6.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-KN-8419-01): tumor purity 0.72, ploidy 2.58, whole-genome doublings 0 (call status: maf_call).

Caution: the most common total copy number in this file is 0 (31,673 autosomal genes at 0 copies), which is not a plausible tumor genome; the fit is treated as unreliable and no deletion or amplification regions are listed.

Homozygous deletions (total copy number 0; autosomes only): 31,673 genes in 17 contiguous regions (regions not listed; see the caution above).

Amplified relative to the modal value (total copy number ≥ 1, i.e. more than twice the modal value of 0; autosomes only): 25,660 genes in 17 contiguous regions (regions not listed; see the caution above).

Autosomal genes at a single copy (total copy number 1): 135. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
